Somatic mutation profile of tumor specimen TARGET-10-PARDEG-09A (aliquot TARGET-10-PARDEG-09A-01D) from TARGET case TARGET-10-PARDEG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,757 days).
Specimen TARGET-10-PARDEG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e998dbbe-f94b-4a29-8279-f074f1c6b47f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDEG-10A (Blood Derived Normal), aliquot TARGET-10-PARDEG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5488a109-f839-432d-bc07-0be6fcdfa1f5

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC85A | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs371781745; called by muse, mutect2, varscan2
- FNDC3B | c.2485C>A p.P829T | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61049730; called by muse, mutect2
- KCND2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs530060196; called by muse, mutect2, varscan2
- MUC16 | c.13735G>T p.A4579S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs935763478; called by muse, mutect2
- RGL2 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); catalogued as rs1480808603; called by muse, mutect2, varscan2
- RXRG | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs1469851984, COSV100717262, COSV63232347; called by muse, mutect2, varscan2
- SCARF2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167691551; called by muse, mutect2
- ZNF479 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.193); catalogued as rs1554400316, COSV58644478; called by muse, mutect2, varscan2
- CFAP65 | c.3056A>T p.D1019V | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CTCF | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCF | c.1406_1407insGG p.C469Wfs*43 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- MBLAC2 | c.382del p.T128Rfs*27 | Frame Shift Del (DEL) | VAF 67/177 reads (38%) | called by mutect2, pindel, varscan2
- PGM2L1 | c.1766G>T p.S589I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2
- TBL1XR1 | c.886_891delinsG p.H296Gfs*2 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by pindel, varscan2*
- TBL1XR1 | c.58+1G>T p.X20_splice | Splice Site (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- CDHR2 | c.150G>A p.A50= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs146915793; called by muse, varscan2
- POLE | c.4041G>T p.L1347= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- SHC2 | c.744G>A p.P248= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs762725996; called by muse, mutect2, varscan2
- SLC5A9 | c.1335C>A p.I445= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1468395531, COSV52584217; called by muse, mutect2
- VSIG4 | c.962+35G>A | Intron (SNP) | VAF 34/64 reads (53%) | catalogued as rs112004626; called by muse, mutect2, varscan2
